Gene-level copy-number profile of tumor specimen C3N-02288-03 from CPTAC case C3N-02288, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 58.7 years (21,432 days).
Specimen C3N-02288-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 72e73fef-6314-4eb1-9c3f-3fd9446715f7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02288-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/8c8a20be-db15-417d-ab05-a71b7ceb6b5f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 57; copy number 1: 87; copy number 2: 10,304; copy number 3: 13,733; copy number 4: 16,920; copy number 5: 8,868; copy number 6: 5,013; copy number 7: 2,588; copy number 8: 670; copy number 9: 104; copy number 10: 3; copy number 13: 4; copy number 21: 3; copy number 27: 3; copy number 29: 13; copy number 33: 17; copy number 36: 1; copy number 42: 3.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,601,416–248,645,278, 3 genes: AC098483.2, OR2T11, OR2T35.
- chr9:25,780,032–29,318,952, 37 genes: LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.1, AL353684.1.
- chr17:3,062,669–3,063,607, 1 gene: OR1D5.
- chr17:18,390,153–18,551,705, 16 genes (within-gene range 0–4): AL353997.5, TBC1D3P4, LINC02076, KRT17P5, YWHAEP2, KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 151 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–522,928, 31 genes, copy number 9: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr2:89,851,791–91,781,169, 52 genes, copy number 9: IGKV2D-40, IGKV1D-39, IGKV2D-38, IGKV1D-37, IGKV2D-36, IGKV1D-35, IGKV3D-34, IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1, LSP1P4, RNA5SP100, DRD5P1, AC027612.2, NKAIN1P2, AC027612.1, KMT5AP2, AC027612.3, GGT8P.
- chr3:181,699,608–181,699,883, 1 gene, copy number 42 (within-gene range 7–42): AC117415.1.
- chr3:181,847,526–183,812,624, 38 genes, copy number 21–42: AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.1, AC084211.1, LINC01994, EIF4EP3, LINC01995, AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2, AC069431.1, ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1, MCCC1, MCCC1-AS1, LAMP3, MCF2L2, B3GNT5, RNA5SP151, LINC00888, SNORA63D, AC092960.2, SNORA63E, AC092960.1, AC092960.3, KLHL6, KLHL6-AS1, AC068769.1, KLHL24, YEATS2, YEATS2-AS1.
- chr3:183,815,922–183,825,594, 1 gene, copy number 29: MAP6D1.
- chr14:18,333,726–18,419,273, 4 genes, copy number 13: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr16:46,469,341–46,931,289, 18 genes, copy number 9: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2.
- chr19:43,192,702–43,269,530, 3 genes, copy number 9: PSG4, CEACAMP10, PSG9.
- chr21:10,612,455–10,649,835, 3 genes, copy number 10: SLC25A15P4, AF254982.1, IGHV1OR21-1.

Autosomal genes at a single copy (total copy number 1): 87. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
